Gene-level copy-number profile of tumor specimen TCGA-AG-A01L-01A from TCGA case TCGA-AG-A01L, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 58.5 years (21,369 days).
Specimen TCGA-AG-A01L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.b076fdea-7e4a-4874-9b30-0bc09e16094f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A01L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/89bb022f-903e-457c-a97f-c4a32b4fd1b8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,970; copy number 3: 11,274; copy number 4: 27,826; copy number 5: 9,877; copy number 7: 886; copy number 8: 243; copy number 9: 51; copy number 10: 387; copy number 11: 706; copy number 14: 2; copy number 18: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A01L-01A-01D-A003-01): tumor purity 0.78, ploidy 3.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,148 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:25,371,974–30,617,597, 102 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr13:33,180,401–57,391,518, 405 genes, copy number 9–11 (within-gene range 8–11) (broad region; genes not listed).
- chr13:59,010,332–114,337,626, 641 genes, copy number 9–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
